Somatic mutation profile of tumor specimen TCGA-13-1487-01A (aliquot TCGA-13-1487-01A-01W-0545-08) from TCGA case TCGA-13-1487, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IV; Tumor grade: GX; Age at diagnosis: 74.4 years (27,176 days).
Specimen TCGA-13-1487-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6396022a-4930-486b-9ae8-798639a91263.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-13-1487-10A (Blood Derived Normal), aliquot TCGA-13-1487-10A-01W-0545-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/16a3dffd-3008-4470-9d41-5c161a2ef9ae

The open-access MAF lists 28 somatic variants for this specimen: 20 protein-altering or splice-affecting, 6 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 17, Silent 6, RNA 2, Frame Shift Del 1, Splice Region 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.710T>A p.M237K | Missense Mutation (SNP) | VAF 105/122 reads (86%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs765848205, COSV52682586, COSV53017093, COSV53037559, COSV53037741; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ADGRB2 | c.1593T>G p.H531Q | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV57079172; called by muse, mutect2, varscan2
- ALDOC | c.910C>T p.R304C | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs376690171; called by muse, mutect2, varscan2
- CARD17 | c.4G>C p.A2P | Missense Mutation (SNP) | VAF 61/318 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.919); catalogued as COSV100995176, COSV65215715; called by muse, mutect2, varscan2
- CCNA2 | c.484A>C p.I162L | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT tolerated (0.88); PolyPhen benign (0); catalogued as COSV52659670; called by mutect2, varscan2
- CDH9 | c.1825G>A p.A609T | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT tolerated (0.17); PolyPhen benign (0.033); catalogued as rs1490543922, COSV50470115; called by muse, mutect2, varscan2
- CST3 | c.357+1G>T p.X119_splice | Splice Site (SNP) | VAF 14/66 reads (21%) | catalogued as COSV65362363; called by muse, mutect2
- EPB41L3 | c.707A>T p.E236V | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.839); catalogued as COSV59468445; called by muse, mutect2, varscan2
- EYA1 | c.314C>G p.T105S | Missense Mutation (SNP) | VAF 85/318 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.019); catalogued as COSV58174519; called by muse, mutect2, varscan2
- JUP | c.1469A>G p.N490S | Missense Mutation (SNP) | VAF 14/16 reads (88%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as COSV60279934; called by muse, varscan2
- LIG4 | c.1519G>T p.G507W | Missense Mutation (SNP) | VAF 3/50 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1164771402, COSV100800085; called by muse, mutect2
- MMP19 | c.1220C>T p.A407V | Missense Mutation (SNP) | VAF 23/47 reads (49%) | SIFT tolerated (0.11); PolyPhen benign (0.056); catalogued as COSV100491281; called by muse, mutect2, varscan2
- PDGFRA | c.1893C>T p.P631= | Splice Region (SNP) | VAF 5/84 reads (6%) | catalogued as COSV99957774; called by muse, mutect2
- PRKCI | c.1008T>G p.N336K | Missense Mutation (SNP) | VAF 17/149 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.754); catalogued as COSV55516929, COSV55522835; called by muse, mutect2, varscan2
- SGIP1 | c.830C>A p.A277D | Missense Mutation (SNP) | VAF 26/85 reads (31%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.037); catalogued as rs1359709055, COSV52766291; called by muse, mutect2, varscan2
- SLC12A5 | c.2207G>A p.G736D (on ENST00000454036 / NM_001134771.2; = p.G713D on NM_020708.5) | Missense Mutation (SNP) | VAF 26/54 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs1363482191, COSV54802328; called by muse, mutect2, varscan2
- SYNE1 | c.2760G>C p.K920N (on ENST00000367255 / NM_182961.4; = p.K927N on NM_033071.3) | Missense Mutation (SNP) | VAF 14/134 reads (10%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.554); catalogued as rs770726839, COSV55109657; called by muse, mutect2
- ZNF713 | c.163C>A p.L55I (on ENST00000633730 / NM_001366796.2; = p.L68I on NM_182633.3) | Missense Mutation (SNP) | VAF 11/19 reads (58%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.579); catalogued as rs1256093146, COSV68888405; called by muse, mutect2, varscan2
- ZNF773 | c.155C>A p.A52D | Missense Mutation (SNP) | VAF 52/231 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1238841318, COSV56590544; called by muse, mutect2, varscan2
- SNRK | c.2142_2145del p.T715Lfs*6 | Frame Shift Del (DEL) | VAF 43/118 reads (36%) | called by mutect2, pindel, varscan2
- ANO3 | c.2946G>A p.*982= | Silent (SNP) | VAF 29/87 reads (33%) | catalogued as rs759722183, COSV56809472; called by muse, mutect2, varscan2
- COL17A1 | c.151C>A p.R51= | Silent (SNP) | VAF 9/32 reads (28%) | catalogued as rs371548263, COSV62229547; called by muse, mutect2, varscan2
- COL4A4 | c.1836A>G p.K612= | Silent (SNP) | VAF 26/69 reads (38%) | catalogued as COSV61636876; called by muse, mutect2, varscan2
- METTL2A | c.1134C>T p.S378= | Silent (SNP) | VAF 51/99 reads (52%) | catalogued as COSV100274332; called by muse, mutect2, varscan2
- MKI67 | c.2659C>T p.L887= | Silent (SNP) | VAF 200/355 reads (56%) | catalogued as rs1387493462, COSV64077115; called by muse, mutect2, varscan2
- NOL4 | c.1434A>G p.R478= | Silent (SNP) | VAF 14/52 reads (27%) | catalogued as COSV52362971; called by muse, mutect2, varscan2
- AC245047.1 | n.1G>C | RNA (SNP) | VAF 42/65 reads (65%) | called by muse, mutect2, varscan2
- HERC2P3 | n.1504T>C | RNA (SNP) | VAF 11/28 reads (39%) | called by muse, mutect2, varscan2
